Gene-level copy-number profile of tumor specimen TCGA-21-1071-01A from TCGA case TCGA-21-1071, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.1 years (24,515 days).
Specimen TCGA-21-1071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ed8baee3-4979-4695-9b67-2d040cfb18ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-1071-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/87073330-fde7-429a-8ec6-c81a8c557a3a

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 120; copy number 1: 118; copy number 2: 325; copy number 3: 5,427; copy number 4: 13,901; copy number 5: 14,329; copy number 6: 14,353; copy number 7: 4,868; copy number 8: 3,648; copy number 9: 253; copy number 10: 1,295; copy number 12: 64; copy number 13: 311; copy number 14: 59; copy number 15: 261; copy number 17: 131; copy number 20: 184; copy number 23: 57; copy number 26: 74; copy number 33: 26; copy number 58: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-21-1071-01A-01D-0685-01): tumor purity 0.29, ploidy 4.35, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 120 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,106,543–30,800,746, 120 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 1,111 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:142,145,454–158,732,489, 277 genes, copy number 13 (broad region; genes not listed).
- chr3:158,732,263–158,784,070, 1 gene, copy number 13 (within-gene range 10–13): AC080013.1.
- chr3:166,160,021–185,825,042, 344 genes, copy number 13–20 (within-gene range 12–20) (broad region; genes not listed).
- chr3:186,717,348–187,297,933, 26 genes, copy number 15: KNG1, PSMD10P2, RNU6-1105P, GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2.
- chr19:28,683,071–37,218,153, 292 genes, copy number 15–23 (within-gene range 7–23) (broad region; genes not listed).
- chr19:37,907,208–41,170,166, 171 genes, copy number 17–58 (within-gene range 7–58) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 118. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
